Somatic mutation profile of tumor specimen TCGA-B8-4146-01B (aliquot TCGA-B8-4146-01B-11D-1669-08) from TCGA case TCGA-B8-4146, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 41.2 years (15,063 days).
Specimen TCGA-B8-4146-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91fe4380-2af4-4ee4-ba8b-67cbb76b8675.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4146-10A (Blood Derived Normal), aliquot TCGA-B8-4146-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2c2e5fa-05f1-4816-82ff-7704648148d1

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Frame Shift Del 6, Silent 6, Splice Region 2, Intron 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARF6 | c.511T>A p.S171T | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV53597414; called by muse, mutect2, varscan2
- ASTN2 | c.2986G>C p.E996Q (on ENST00000313400 / NM_001365069.1; = p.E945Q on NM_014010.5) | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.778); catalogued as COSV56001440; called by muse, mutect2, varscan2
- CACNA1S | c.220A>C p.M74L | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.822); catalogued as COSV62937979; called by muse, mutect2, varscan2
- CACNB4 | c.1116A>G p.P372= | Splice Region (SNP) | VAF 8/24 reads (33%) | catalogued as COSV52391153; called by muse, mutect2, varscan2
- CDAN1 | c.1232C>G p.A411G | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.163); catalogued as COSV51158295; called by muse, mutect2, varscan2
- CHD8 | c.2809C>G p.L937V (on ENST00000646647 / NM_001170629.2; = p.L658V on NM_020920.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV67870028; called by muse, varscan2
- CLN8 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58669936; called by muse, mutect2, varscan2
- EVPL | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100043974, COSV56908891; called by muse, mutect2, varscan2
- HSPA9 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.25); catalogued as COSV51863996; called by muse, mutect2, varscan2
- KIAA0232 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56924091; called by muse, mutect2, varscan2
- KLHL13 | c.1853del p.K618Rfs*48 | Frame Shift Del (DEL) | VAF 26/173 reads (15%) | catalogued as COSV53253444; called by mutect2, pindel, varscan2
- LIPC | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753168442, COSV54421304; called by muse, mutect2, varscan2
- MED13 | c.6233C>G p.P2078R | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67262643; called by muse, mutect2, varscan2
- NLRC4 | c.353A>T p.Y118F | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61591946; called by muse, mutect2, varscan2
- OR7C1 | c.313A>T p.T105S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1194385545, COSV50182999; called by muse, mutect2, varscan2
- OVCH1 | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV58961095; called by muse, mutect2, varscan2
- PEX5L | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV55842110; called by muse, mutect2, varscan2
- SH2D7 | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51947914; called by muse, mutect2, varscan2
- SREBF1 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs773391894, COSV55415597; called by muse, mutect2, varscan2
- TBC1D8B | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV52177240; called by muse, mutect2
- ZBED4 | c.1766G>C p.G589A | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53464541; called by muse, mutect2, varscan2
- ZNF518B | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58721901; called by muse, mutect2, varscan2
- ZNF669 | c.390A>G p.G130= | Splice Region (SNP) | VAF 26/101 reads (26%) | catalogued as COSV58537171; called by muse, mutect2, varscan2
- ZNF669 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV58537193; called by muse, mutect2, varscan2
- HIPK2 | c.3374del p.G1125Afs*22 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- HOXC8 | c.285del p.R96Dfs*34 | Frame Shift Del (DEL) | VAF 69/254 reads (27%) | called by mutect2, pindel, varscan2
- PHC3 | c.2819_2832del p.E940Gfs*3 (on ENST00000494943 / NM_001308116.2; = p.E952Gfs*3 on NM_024947.4) | Frame Shift Del (DEL) | VAF 48/165 reads (29%) | called by mutect2, pindel
- SLC22A9 | c.715_716del p.C239Pfs*52 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by pindel, varscan2
- ZNF721 | c.654del p.F218Lfs*7 (on ENST00000338977; = p.F230Lfs*7 on NM_133474.4) | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- ABHD8 | c.870C>A p.I290= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV56044443; called by muse, mutect2, varscan2
- ASB8 | c.558A>G p.T186= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs1361624214, COSV56656614; called by muse, mutect2, varscan2
- ATP2A1 | c.600C>A p.V200= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV63920401; called by muse, mutect2, varscan2
- DENND10 | c.423C>A p.G141= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV63857488; called by muse, mutect2, varscan2
- LRRC55 | c.819G>A p.V273= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV73006401; called by muse, mutect2, varscan2
- ZNF107 | c.2271C>T p.F757= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1269610819, COSV61327520; called by muse, mutect2, varscan2
- DST | c.4297-4493C>T | Intron (SNP) | VAF 52/195 reads (27%) | catalogued as rs764734340, COSV55004953; called by muse, mutect2, varscan2
- GLRXP3 | n.83G>A | RNA (SNP) | VAF 36/138 reads (26%) | catalogued as rs1371298942; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85358dup | Intron (INS) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
